Somatic mutation profile of tumor specimen TCGA-CQ-7071-01A (aliquot TCGA-CQ-7071-01A-12D-A30E-08) from TCGA case TCGA-CQ-7071, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 76.5 years (27,928 days).
Specimen TCGA-CQ-7071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7e8071e-0a04-42ae-8e84-ef1c013247c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-7071-10A (Blood Derived Normal), aliquot TCGA-CQ-7071-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bce64af7-b230-4d19-8452-284f3b6d2758

The open-access MAF lists 496 somatic variants for this specimen: 394 protein-altering or splice-affecting, 95 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 345, Silent 95, Nonsense Mutation 29, Splice Site 7, Frame Shift Del 6, 5'UTR 3, In Frame Del 2, Splice Region 2, Frame Shift Ins 2, Intron 2, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs754189348, COSV99966665; called by muse, mutect2, varscan2
- AASS | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100741797, COSV62790502; called by muse, mutect2, varscan2
- ABCA3 | c.3237G>T p.Q1079H | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100068618; called by muse, mutect2, varscan2
- ABCB1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199852575, COSV55948242; called by muse, mutect2, varscan2
- ACKR1 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100929573; called by muse, mutect2, varscan2
- ACSF3 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs747598756, COSV100441373; called by muse, mutect2, varscan2
- ADAMTS19 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as COSV99179010, COSV99183660; called by muse, mutect2, varscan2
- ADCK5 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100450486; called by muse, mutect2, varscan2
- ADGRA1 | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV100811026; called by muse, mutect2, varscan2
- ADH1A | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV99265808; called by muse, mutect2, varscan2
- ADRM1 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99440362; called by muse, mutect2
- AF196969.1 | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as CM081231, COSV99339344; called by muse, mutect2, varscan2
- AKNA | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99800424; called by muse, mutect2, varscan2
- AKNA | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV99800428; called by muse, mutect2, varscan2
- AL031681.2 | c.3257G>T p.S1086I | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as rs760372214, COSV100917006; called by muse, mutect2, varscan2
- ANK3 | c.11716T>A p.C3906S | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as rs142931189; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs763436404, COSV99783534; called by mutect2, varscan2
- ANKRD24 | c.3379G>C p.D1127H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99517590; called by muse, mutect2, varscan2
- APTX | c.426C>G p.S142R | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.169); catalogued as rs750349898, COSV100541368; called by muse, mutect2, varscan2
- ARHGAP26 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as rs781680770, COSV50824683; called by muse, mutect2, varscan2
- ARL13A | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs766355429, COSV65880327; called by muse, mutect2, varscan2
- ASPM | c.6997G>A p.E2333K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.074); catalogued as COSV99660482; called by muse, mutect2
- ATP2B2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749396633, COSV59488346, COSV59493792, COSV59510669; called by muse, mutect2, varscan2
- AWAT1 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV100997205; called by muse, mutect2, varscan2
- BCL6B | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV99546685; called by muse, mutect2, varscan2
- BEND3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100944616; called by muse, mutect2, varscan2
- BIRC6 | c.9380C>T p.S3127L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101428346; called by muse, mutect2, varscan2
- BNIP5 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs193920980, COSV71325445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6523G>C p.E2175Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs876658412, COSV66463236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTAF1 | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as COSV99795416; called by muse, mutect2, varscan2
- BTAF1 | c.4093G>A p.E1365K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV56437949; called by muse, mutect2, varscan2
- BTBD7 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV100597896; called by muse, mutect2, varscan2
- BTD | c.1354G>T p.G452* | Nonsense Mutation (SNP) | VAF 36/134 reads (27%) | catalogued as COSV100329609; called by muse, mutect2, varscan2
- BTNL3 | c.971G>C p.R324T | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100732213, COSV61565196; called by muse, mutect2, varscan2
- C12orf40 | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as COSV100210165; called by muse, mutect2, varscan2
- C2orf78 | c.2101G>C p.E701Q | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV68519359; called by muse, mutect2, varscan2
- C3orf62 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55538979; called by muse, mutect2
- C8A | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as COSV100776512; called by muse, mutect2, varscan2
- CA4 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV56280913; called by muse, mutect2, varscan2
- CACNA2D1 | c.2875G>A p.E959K (on ENST00000356253 / NM_001366867.1; = p.E947K on NM_000722.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100666723; called by muse, mutect2, varscan2
- CACNA2D1 | c.1786G>A p.D596N (on ENST00000356253 / NM_001366867.1; = p.D577N on NM_000722.4) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as COSV100666724, COSV100666726; called by muse, mutect2, varscan2
- CAND1 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101598277; called by muse, mutect2, varscan2
- CARD6 | c.2365C>T p.H789Y | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99620859; called by muse, mutect2, varscan2
- CASP8 | c.72C>G p.F24L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99965347; called by muse, mutect2, varscan2
- CASP8 | c.999C>G p.I333M (on ENST00000432109 / NM_033355.3; = p.I350M on NM_001228.4) | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51845155; called by muse, mutect2, varscan2
- CATIP | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.031); catalogued as COSV99179550; called by muse, mutect2, varscan2
- CCDC180 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100826823; called by muse, mutect2, varscan2
- CCDC42 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99549811; called by muse, mutect2, varscan2
- CCT5 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs958616251, COSV54725358, COSV99725389; called by muse, mutect2, varscan2
- CD274 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV99061052; called by muse, mutect2, varscan2
- CD300LD | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1262561996, COSV100032472; called by muse, mutect2, varscan2
- CD59 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV100681242; called by muse, varscan2
- CDC37 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV99705788; called by muse, mutect2, varscan2
- CDC42BPB | c.1892C>G p.A631G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100775467; called by muse, mutect2
- CDH18 | c.1712C>G p.S571C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV99935509; called by muse, mutect2, varscan2
- CHRM3 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as rs1446692422, COSV99698549; called by muse, mutect2, varscan2
- CHST12 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs905098497, COSV51676142; called by muse, mutect2, varscan2
- CLMN | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as rs1408387592, COSV100112455; called by muse, mutect2, varscan2
- CLSTN1 | c.2641C>T p.R881W (on ENST00000377298 / NM_001009566.3; = p.R871W on NM_014944.4) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754798318, COSV100740226; called by muse, mutect2, varscan2
- CLTC | c.2356G>C p.D786H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99292375; called by muse, mutect2, varscan2
- CLVS2 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51568515; called by muse, mutect2, varscan2
- CMYA5 | c.8338G>T p.E2780* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101484103; called by muse, mutect2, varscan2
- CNOT1 | c.3656C>T p.S1219L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99800358; called by muse, mutect2, varscan2
- CNTN3 | c.1861G>T p.G621C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99724678; called by muse, mutect2, varscan2
- COG7 | c.1608G>C p.Q536H | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.806); catalogued as COSV100207587; called by muse, mutect2, varscan2
- COL4A2 | c.4033G>C p.E1345Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.932); catalogued as COSV100847369, COSV64625464, COSV64628369; called by muse, mutect2, varscan2
- COL4A5 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM050559, COSV100087952; called by muse, mutect2, varscan2
- COL6A2 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.906); catalogued as COSV100153649, COSV56005713; called by muse, mutect2, varscan2
- COQ5 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 104/449 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99942324; called by muse, mutect2, varscan2
- CR1 | c.5792G>C p.G1931A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100887648; called by muse, mutect2, varscan2
- CREBBP | c.4040G>A p.R1347Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV52125338; called by muse, mutect2, varscan2
- CRYBA4 | c.396G>C p.M132I | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100697809; called by muse, mutect2, varscan2
- CUL1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV100296702; called by muse, mutect2, varscan2
- CXorf56 | c.546G>C p.K182N (on ENST00000536133 / NM_001170570.2; = p.K196N on NM_022101.4) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV100233399; called by muse, mutect2, varscan2
- CYC1 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1266291299, COSV100010432; called by muse, mutect2, varscan2
- CYP27B1 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 43/240 reads (18%) | catalogued as COSV99141568; called by muse, mutect2, varscan2
- DBNDD1 | c.292G>A p.E98K (on ENST00000002501 / NM_001042610.3; = p.E118K on NM_024043.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs770230072, COSV99136479; called by muse, varscan2
- DBX1 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV57053383; called by muse, mutect2, varscan2
- DDB2 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs781655324, COSV57038633; called by muse, mutect2, varscan2
- DDX23 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs778918285, COSV100339851, COSV57285491; called by muse, mutect2, varscan2
- DDX39B | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100385433; called by muse, varscan2
- DDX39B | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 34/130 reads (26%) | catalogued as COSV100385435, COSV58214075; called by muse, varscan2
- DENND2B | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100567531; called by muse, mutect2, varscan2
- DNAH2 | c.13261C>G p.L4421V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV101209328, COSV101209380; called by muse, mutect2, varscan2
- DNAH5 | c.12138C>G p.I4046M | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99450453; called by muse, mutect2, varscan2
- DNAL4 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV53308750, COSV53309017, COSV99326134; called by muse, mutect2, varscan2
- DNMT3B | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52423887; called by muse, mutect2, varscan2
- DOCK10 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV51419711, COSV99289761; called by muse, mutect2, varscan2
- DOP1A | c.5341C>T p.Q1781* | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | catalogued as COSV104377801, COSV99382065; called by muse, mutect2, varscan2
- DPYSL4 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV100633953; called by muse, mutect2, varscan2
- DSCC1 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV100558342; called by muse, mutect2, varscan2
- DTX3L | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV56144989, COSV99950050; called by muse, mutect2, varscan2
- ECI2 | c.48G>C p.P16= | Splice Region (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100326508; called by muse, mutect2, varscan2
- EDC4 | c.1027C>G p.H343D | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100739168; called by muse, mutect2, varscan2
- EGFL8 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV100246969; called by muse, mutect2, varscan2
- ELK4 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV56984818; called by muse, mutect2, varscan2
- EMC7 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as COSV99854881; called by muse, mutect2, varscan2
- EMILIN2 | c.2260G>C p.D754H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1031831897, COSV99598581; called by muse, mutect2, varscan2
- ENO3 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); catalogued as COSV99236563; called by muse, mutect2, varscan2
- ENOX2 | c.232C>T p.P78S (on ENST00000338144 / NM_001382520.1; = p.P49S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100584210; called by muse, mutect2, varscan2
- EOLA1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs370085115, COSV100828416; called by muse, mutect2, varscan2
- EPG5 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV99957411; called by muse, mutect2, varscan2
- ERC1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1474649916, COSV100706133; called by muse, mutect2, varscan2
- ERMP1 | c.2360C>A p.S787Y | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV99284553; called by muse, mutect2, varscan2
- ESD | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.044); catalogued as COSV101099162; called by muse, mutect2, varscan2
- FAM120C | c.3115G>A p.A1039T | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs782023167, COSV60260319, COSV60263078; called by muse, mutect2, varscan2
- FAM171A1 | c.2572G>C p.E858Q | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100968289, COSV65315866; called by muse, mutect2, varscan2
- FAM47A | c.1114G>T p.G372W | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV60497497; called by muse, varscan2
- FAM9C | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs767998958, COSV100452817, COSV100452921; called by muse, mutect2, varscan2
- FANCI | c.2672C>T p.S891L (on ENST00000310775 / NM_001376911.1; = p.S831L on NM_018193.3) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs773239544, COSV100168065; called by muse, mutect2, varscan2
- FASTKD3 | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.049); catalogued as rs779187340, COSV99241769; called by muse, varscan2
- FASTKD3 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99241770; called by muse, varscan2
- FASTKD5 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs1455858340, COSV99418021; called by muse, mutect2, varscan2
- FBXW5 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99812520; called by muse, mutect2, varscan2
- FEM1B | c.1361C>G p.S454C | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as COSV100183673; called by muse, mutect2, varscan2
- FGR | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as rs779407504, COSV100925838; called by muse, mutect2, varscan2
- FHIT | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs149317894; called by muse, mutect2, varscan2
- FILIP1L | c.2009C>T p.A670V (on ENST00000354552 / NM_182909.3; = p.A430V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100496917; called by muse, mutect2, varscan2
- FLNA | c.4177G>C p.E1393Q | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100774752; called by muse, mutect2, varscan2
- FNIP1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100330456; called by muse, mutect2, varscan2
- FZD2 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV100190482; called by muse, mutect2, varscan2
- FZD7 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53808382, COSV53810943; called by muse, varscan2
- GAD2 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99393356; called by muse, mutect2, varscan2
- GCNA | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV101032399, COSV101032542; called by muse, mutect2, varscan2
- GGH | c.144G>C p.M48I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV99478882; called by muse, mutect2, varscan2
- GJA10 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101005364; called by muse, mutect2, varscan2
- GML | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99638327; called by muse, mutect2, varscan2
- GNPDA1 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as rs1281128211, COSV60942544; called by muse, mutect2, varscan2
- GNRHR | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99892190; called by muse, mutect2, varscan2
- GOLGA4 | c.5108C>T p.S1703L | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100728944, COSV62711119; called by muse, mutect2, varscan2
- GPC3 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV100893007; called by muse, mutect2
- GPR173 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100212279, COSV60234943; called by muse, mutect2, varscan2
- GPR176 | c.1397C>A p.S466* | Nonsense Mutation (SNP) | VAF 33/124 reads (27%) | catalogued as rs1200334904, COSV100137234; called by muse, mutect2, varscan2
- GRIN2A | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100410049; called by muse, mutect2, varscan2
- GSTM3 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99860238; called by muse, mutect2, varscan2
- GTF3C5 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as rs1397107421, COSV100565190, COSV100565434; called by muse, mutect2, varscan2
- H2BC15 | c.73_75del p.K25del | In Frame Del (DEL) | VAF 58/245 reads (24%) | catalogued as rs759275537; called by pindel, varscan2
- HACE1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99493801; called by muse, mutect2, varscan2
- HCAR3 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100811634, COSV63675712; called by muse, mutect2, varscan2
- HDAC6 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV100490897; called by muse, mutect2, varscan2
- HECTD2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99978635; called by muse, mutect2, varscan2
- HEPH | c.3309G>C p.K1103N (on ENST00000343002; = p.K836N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV100295550, COSV57959020; called by muse, mutect2, varscan2
- HLA-A | c.895+2T>C p.X299_splice | Splice Site (SNP) | VAF 38/73 reads (52%) | catalogued as COSV65145442; called by muse, mutect2, varscan2
- HLA-B | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs137854653, CM1412111, COSV69520364, COSV69521019; called by muse, mutect2, varscan2
- HLA-B | c.73+1G>C p.X25_splice | Splice Site (SNP) | VAF 24/39 reads (62%) | catalogued as COSV101318086; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1343992220, COSV100079640; called by muse, mutect2, varscan2
- HOXC6 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99679083; called by muse, mutect2, varscan2
- HUWE1 | c.11002G>A p.E3668K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV99472615; called by muse, mutect2, varscan2
- ICE1 | c.1178C>G p.S393* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99664895; called by muse, mutect2, varscan2
- ICE1 | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99664898; called by muse, mutect2, varscan2
- IL1RAPL1 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100147486, COSV56262460; called by muse, mutect2, varscan2
- IL1RL1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV99294159; called by muse, mutect2, varscan2
- IL1RL2 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1165959236, COSV51814508, COSV99960726; called by muse, mutect2, varscan2
- ILRUN | c.529C>T p.L177F (on ENST00000374023 / NM_024294.4; = p.L111F on NM_022758.6) | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV100927239; called by muse, mutect2, varscan2
- INPP4B | c.2273A>C p.E758A | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV99524919; called by muse, mutect2, varscan2
- INTS4 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101417203; called by muse, mutect2, varscan2
- IQSEC3 | c.2877C>G p.F959L (on ENST00000538872 / NM_001170738.2; = p.F656L on NM_015232.1) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV100407272, COSV58283153; called by muse, mutect2, varscan2
- ITPR1 | c.2569G>A p.D857N (on ENST00000354582; = p.D842N on NM_002222.7) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV100231425, COSV56978341; called by muse, mutect2
- JADE2 | c.855C>T p.V285= | Splice Region (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99253303; called by muse, mutect2, varscan2
- JADE3 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99509932; called by muse, mutect2, varscan2
- KCNH8 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV100110012; called by muse, mutect2
- KCNQ5 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748704876, COSV59665678; called by muse, mutect2, varscan2
- KCTD9 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as COSV99648604; called by muse, mutect2, varscan2
- KDM3A | c.2274C>G p.F758L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100460538; called by muse, mutect2, varscan2
- KDM5C | c.3070G>T p.E1024* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV64767602; called by muse, mutect2, varscan2
- KDR | c.3608A>G p.E1203G | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV99817877; called by muse, mutect2, varscan2
- KIAA0232 | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs376546237, COSV100300760; called by muse, mutect2, varscan2
- KIAA0753 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV100810612; called by muse, mutect2, varscan2
- KIAA1522 | c.2392C>G p.Q798E (on ENST00000373480 / NM_001198972.2; = p.Q857E on NM_020888.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99614700, COSV99615330; called by muse, mutect2, varscan2
- KIZ | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99851803; called by muse, mutect2, varscan2
- KMT5B | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV100069969; called by muse, mutect2, varscan2
- KNL1 | c.2689G>A p.D897N (on ENST00000346991 / NM_170589.5; = p.D871N on NM_144508.5) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as rs1186561771, COSV100706564; called by muse, mutect2, varscan2
- KPNA1 | c.539C>G p.S180* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100724240; called by muse, mutect2, varscan2
- L1CAM | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100649196; called by muse, mutect2, varscan2
- LAMA2 | c.7148G>C p.R2383P | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV101370513; called by muse, mutect2, varscan2
- LINGO2 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as COSV100430597, COSV100430627; called by muse, mutect2, varscan2
- LINS1 | c.87C>G p.I29M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as rs144523618; called by muse, mutect2, varscan2
- LMNB2 | c.1536G>C p.E512D | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99296005; called by muse, mutect2, varscan2
- LRRC15 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); catalogued as COSV100752743; called by muse, mutect2, varscan2
- LRRCC1 | c.3016G>C p.E1006Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100835470; called by muse, mutect2, varscan2
- LRRFIP1 | c.1701G>C p.K567N (on ENST00000392000 / NM_001137552.2; = p.K543N on NM_004735.4) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV55254842, COSV99790845; called by muse, mutect2, varscan2
- LRRK2 | c.248C>G p.S83* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100110349; called by muse, mutect2, varscan2
- LY75 | c.2743+2T>C p.X915_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99716517; called by muse, mutect2, varscan2
- MAGI3 | c.2684G>A p.G895E | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100289316; called by muse, mutect2, varscan2
- MAN1B1 | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100857367; called by muse, mutect2, varscan2
- MAP4K3 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99810496; called by muse, mutect2, varscan2
- MCHR1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs369827677; called by muse, mutect2, varscan2
- MDN1 | c.9833G>A p.R3278K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101021421; called by muse, mutect2, varscan2
- MROH9 | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100882798; called by muse, mutect2, varscan2
- MRPL52 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs1440217092, COSV61288506; called by muse, mutect2, varscan2
- MRPS23 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100551446; called by muse, mutect2, varscan2
- MRTFB | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as COSV100371345; called by muse, mutect2, varscan2
- MRTFB | c.1056G>C p.Q352H | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100371347; called by muse, mutect2, varscan2
- MTMR3 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV100070921; called by muse, mutect2, varscan2
- MYADM | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.192); catalogued as rs1438440073, COSV100425087; called by muse, mutect2, varscan2
- MYH13 | c.3130C>A p.Q1044K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV99354205; called by muse, mutect2, varscan2
- MYH7B | c.4827C>G p.I1609M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99328456; called by muse, mutect2, varscan2
- MYO1A | c.1515C>G p.I505M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100270971; called by muse, mutect2, varscan2
- N4BP3 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99200697; called by muse, mutect2, varscan2
- NDST4 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV99996669; called by muse, mutect2, varscan2
- NDUFB9 | c.129G>C p.L43F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as COSV99412832; called by muse, mutect2, varscan2
- NF1 | c.7819G>A p.E2607K (on ENST00000358273 / NM_001042492.3; = p.E2586K on NM_000267.3) | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV62227319; called by muse, mutect2, varscan2
- NKD1 | c.537G>C p.K179N | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51692420, COSV99194060; called by muse, mutect2, varscan2
- NLRC4 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100707401; called by muse, mutect2, varscan2
- NOSTRIN | c.799G>A p.E267K (on ENST00000317647 / NM_001039724.4; = p.E189K on NM_052946.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV100473656; called by muse, mutect2, varscan2
- NOTCH1 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53037156, COSV99488548; called by muse, mutect2, varscan2
- NOTCH1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53110809; called by muse, mutect2, varscan2
- NRK | c.77C>G p.S26* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99688023; called by muse, mutect2, varscan2
- NRK | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV99688024; called by muse, mutect2, varscan2
- NRXN1 | c.3647G>A p.R1216H | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765200132, COSV60486467, COSV60508284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUCKS1 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100900743; called by muse, mutect2, varscan2
- ODC1 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs753595527, COSV99301302; called by muse, mutect2, varscan2
- OLFM4 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 52/171 reads (30%) | catalogued as COSV99524375; called by muse, mutect2, varscan2
- OR2D3 | c.927G>C p.R309S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs746113348, COSV53493044, COSV99549663; called by muse, mutect2, varscan2
- OR4S2 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 83/257 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100412669; called by muse, mutect2, varscan2
- ORC3 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100005976; called by muse, mutect2, varscan2
- PAK2 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100506153; called by muse, mutect2, varscan2
- PCDH19 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM134957, COSV99719942; called by muse, mutect2, varscan2
- PCDH9 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100121194; called by muse, mutect2, varscan2
- PCNA | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV99176992; called by muse, mutect2, varscan2
- PDZD2 | c.4102C>T p.H1368Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99225273; called by muse, mutect2, varscan2
- PFKL | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62465876; called by muse, mutect2, varscan2
- PGM2L1 | c.1325G>C p.G442A | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV104402518, COSV99994943; called by muse, mutect2, varscan2
- PGM5 | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs782212102, COSV101123461; called by muse, mutect2, varscan2
- PHF23 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV50038492, COSV99138550; called by muse, mutect2, varscan2
- PHYH | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1392704631, COSV99538182; called by muse, mutect2, varscan2
- PKD1 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774555028, COSV99238255; called by muse, mutect2, varscan2
- PKD1L1 | c.6642G>T p.R2214S | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99219973; called by muse, mutect2, varscan2
- PKHD1 | c.3650C>G p.S1217* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100583311; called by muse, mutect2, varscan2
- PLAU | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV101032348, COSV104425346; called by muse, mutect2, varscan2
- PLRG1 | c.1530G>C p.K510N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100123130; called by muse, mutect2, varscan2
- PLXNB3 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.162); catalogued as rs781991732, COSV100737493; called by muse, mutect2, varscan2
- PMP22 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749165928, CM111889, COSV56601919; called by muse, mutect2, varscan2
- PMPCA | c.1521G>C p.Q507H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV100867774; called by muse, mutect2, varscan2
- PMS2 | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 108/401 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1313318, COSV99764256; called by muse, mutect2, varscan2
- PNLIPRP2 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100077785, COSV53944451; called by muse, mutect2, varscan2
- PNPLA6 | c.359C>T p.S120F (on ENST00000414982 / NM_001166111.2; = p.S72F on NM_006702.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs909622359, COSV99653801; called by muse, mutect2, varscan2
- PNPLA6 | c.1387C>G p.R463G (on ENST00000414982 / NM_001166111.2; = p.R415G on NM_006702.5) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.203); catalogued as rs1016628214, COSV55382097, COSV99653803; called by muse, mutect2, varscan2
- PPFIBP1 | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99944871; called by muse, mutect2, varscan2
- PPP1R10 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV100919854; called by muse, mutect2, varscan2
- PRDM2 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as COSV99341829; called by muse, mutect2, varscan2
- PRKCSH | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV99371651; called by muse, mutect2, varscan2
- PRLR | c.989C>G p.S330* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99184432; called by muse, mutect2, varscan2
- PROM1 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV101477087; called by muse, mutect2, varscan2
- PRRC2A | c.4051G>A p.V1351M | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV65688005; called by muse, mutect2, varscan2
- PTPN14 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65286124; called by muse, mutect2, varscan2
- PTPRH | c.657G>C p.Q219H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs764924895, COSV99671077; called by muse, mutect2, varscan2
- PTX4 | c.1369G>A p.A457T (on ENST00000447419 / NM_001328608.2; = p.A452T on NM_001013658.1) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.2); catalogued as rs1378725974, COSV99560498; called by muse, mutect2, varscan2
- RAB18 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.092); catalogued as rs959454974, COSV100803835; called by muse, mutect2, varscan2
- RABAC1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs557036843, COSV99706112; called by muse, mutect2
- RAD52 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99942589; called by muse, mutect2, varscan2
- RAD54B | c.2119A>G p.N707D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100279847; called by muse, mutect2, varscan2
- RALGAPB | c.1982G>C p.R661T | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99485334; called by muse, mutect2, varscan2
- RAP1GAP | c.1618C>G p.Q540E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV51575635, COSV99265336; called by muse, mutect2, varscan2
- RB1 | c.2085G>C p.M695I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV57317613, COSV99925033; called by muse, mutect2, varscan2
- RBAK | c.1346G>C p.R449T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100806678; called by muse, mutect2, varscan2
- RC3H1 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV99281408; called by muse, mutect2, varscan2
- RDH10 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV99536336; called by muse, mutect2, varscan2
- REL | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV99692132; called by muse, mutect2, varscan2
- REV3L | c.9335G>A p.R3112Q | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs375494302; called by muse, mutect2, varscan2
- REV3L | c.3404G>C p.R1135T | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV100725256; called by muse, mutect2, varscan2
- RGR | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV63894017; called by muse, mutect2, varscan2
- RNF13 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV99526059; called by muse, mutect2, varscan2
- RNF149 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs748563357, COSV99766608, COSV99766784; called by muse, mutect2, varscan2
- ROBO2 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59934307; called by muse, mutect2, varscan2
- ROCK1 | c.2874G>C p.E958D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV101296404; called by muse, mutect2, varscan2
- RPRD2 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as COSV100955098; called by muse, mutect2, varscan2
- RPUSD3 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs115670492; called by muse, mutect2, varscan2
- RTF1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 117/417 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV101047867; called by muse, mutect2, varscan2
- RWDD1 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV100888279, COSV63972342; called by muse, mutect2, varscan2
- RYR1 | c.5710G>A p.E1904K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV62114992; called by muse, mutect2, varscan2
- SCN10A | c.3733C>T p.P1245S | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV101479417; called by muse, mutect2, varscan2
- SCN2A | c.4072C>T p.L1358F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV51833777; called by muse, mutect2, varscan2
- SCN8A | c.5035G>A p.E1679K | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs796053225, COSV61980056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1B | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV56303229; called by muse, mutect2, varscan2
- SCO1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.049); catalogued as COSV99703556; called by muse, mutect2, varscan2
- SEMA3F | c.834C>A p.F278L | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV50030426, COSV99137538; called by muse, mutect2, varscan2
- SHROOM4 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV99173597; called by muse, mutect2, varscan2
- SIGLEC5 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV99707544; called by muse, mutect2, varscan2
- SIK3 | c.789G>C p.Q263H (on ENST00000445177 / NM_001366686.2; = p.Q269H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV99408123; called by muse, mutect2, varscan2
- SIRT2 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV99979437; called by muse, mutect2, varscan2
- SIX4 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV99382286; called by muse, mutect2, varscan2
- SLC12A1 | c.2460C>G p.D820E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV101118812; called by muse, mutect2, varscan2
- SLC17A8 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100035592; called by muse, mutect2, varscan2
- SLC30A7 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as rs778750431, COSV100725530; called by muse, mutect2, varscan2
- SLC38A5 | c.750G>C p.Q250H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100476543; called by muse, mutect2, varscan2
- SLC6A9 | c.621C>G p.F207L (on ENST00000360584 / NM_201649.4; = p.F153L on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV100746282; called by muse, mutect2, varscan2
- SLFN12 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100513097; called by muse, mutect2, varscan2
- SLIT2 | c.3640C>T p.R1214C | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV56566151; called by muse, mutect2, varscan2
- SLIT2 | c.4137-1G>C p.X1379_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99884322; called by muse, mutect2, varscan2
- SOAT1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100858975; called by muse, mutect2, varscan2
- SP140L | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.943); catalogued as COSV54744600, COSV54749971; called by muse, mutect2, varscan2
- SPAG16 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.656); catalogued as rs1037134648, COSV100533330, COSV59082101; called by muse, mutect2, varscan2
- SPATA31D1 | c.3080G>T p.R1027I | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as COSV61200223; called by muse, mutect2
- SPEN | c.5704C>T p.R1902W | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776525901, COSV65362316; called by muse, mutect2, varscan2
- SPOCK1 | c.186+1G>A p.X62_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99969548; called by muse, mutect2
- SPTBN1 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 52/188 reads (28%) | catalogued as COSV100442747; called by muse, mutect2, varscan2
- STAB2 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV101186010, COSV66347467; called by muse, mutect2, varscan2
- STK11 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV100480491, COSV58825697; called by muse, mutect2, varscan2
- STPG2 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as rs948656925, COSV99759631; called by muse, mutect2, varscan2
- SULF1 | c.1503C>A p.D501E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99483197; called by muse, mutect2, varscan2
- SUPT6H | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100112467, COSV58931283; called by muse, mutect2, varscan2
- SYNE1 | c.10513G>A p.E3505K (on ENST00000367255 / NM_182961.4; = p.E3512K on NM_033071.3) | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as COSV99566577; called by muse, mutect2, varscan2
- SYT17 | c.1295C>A p.S432* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100810744; called by muse, mutect2, varscan2
- TACC1 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99393543; called by muse, mutect2, varscan2
- TAF6L | c.204C>A p.F68L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99585234; called by muse, mutect2, varscan2
- TAMM41 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV99808828; called by muse, mutect2, varscan2
- TAS2R16 | c.745G>C p.G249R | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.125); catalogued as COSV99972264; called by muse, mutect2, varscan2
- TBX22 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs761750322, COSV64786341; called by muse, mutect2, varscan2
- TBX3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs1565862637, COSV99983825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF7L2 | c.1765A>G p.I589V (on ENST00000355995 / NM_001367943.1; = p.I566V on NM_030756.5) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs899775528, COSV99525924; called by muse, mutect2, varscan2
- TCOF1 | c.3301G>A p.D1101N (on ENST00000377797 / NM_001135243.1; = p.D1024N on NM_000356.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as rs1193457959, COSV100077602; called by muse, mutect2, varscan2
- TDRD6 | c.4927G>C p.E1643Q | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV100287712; called by muse, mutect2, varscan2
- TDRKH | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100917968; called by muse, mutect2, varscan2
- TENM3 | c.3647G>A p.R1216K | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV69320615; called by muse, mutect2, varscan2
- TGFBR2 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99847231; called by muse, mutect2, varscan2
- TGFBR2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM064336, COSV55442699; called by muse, mutect2, varscan2
- THNSL1 | c.45_46del p.K16Mfs*4 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs944458549; called by mutect2, pindel, varscan2
- TLL2 | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100780318; called by muse, mutect2, varscan2
- TLN2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100169155; called by muse, mutect2, varscan2
- TLR8 | c.1678G>A p.D560N (on ENST00000218032 / NM_138636.5; = p.D578N on NM_016610.4) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99487059; called by muse, mutect2, varscan2
- TLR9 | c.2047G>C p.D683H | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100645665; called by muse, mutect2, varscan2
- TM4SF18 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99937907; called by muse, mutect2, varscan2
- TMEM132E | c.887G>T p.G296V (on ENST00000321639; = p.G386V on NM_001304438.2) | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100396398, COSV58699177; called by muse, varscan2
- TMEM47 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV52067176, COSV99327705; called by muse, mutect2, varscan2
- TNFRSF8 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV99821535; called by muse, mutect2, varscan2
- TNXB | c.7923G>C p.E2641D (on ENST00000647633; = p.E2394D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as COSV100926389; called by muse, mutect2, varscan2
- TNXB | c.5078G>A p.G1693E (on ENST00000647633; = p.G1446E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs760049473, COSV100926390; called by muse, mutect2, varscan2
- TOGARAM1 | c.5153A>G p.N1718S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100818067; called by muse, mutect2, varscan2
- TPTE | c.1414C>G p.L472V (on ENST00000618007 / NM_199261.4; = p.L454V on NM_199259.4) | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.196); catalogued as rs1414458154; called by muse, mutect2
- TRIAP1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.197); catalogued as COSV99984879; called by muse, mutect2, varscan2
- TRIM4 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs1461617061, COSV100458443; called by muse, mutect2
- TTC8 | c.919G>C p.E307Q (on ENST00000338104 / NM_001288781.1; = p.E291Q on NM_144596.4) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100581386; called by muse, mutect2, varscan2
- TTN | c.40585G>A p.D13529N (on ENST00000591111; = p.D6105N on NM_003319.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | PolyPhen possibly damaging (0.797); catalogued as rs751407435, COSV100615933; called by muse, mutect2, varscan2
- TUBGCP3 | c.2689C>G p.L897V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as COSV99996929; called by muse, mutect2, varscan2
- TULP4 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as rs1229743903, COSV100893544; called by muse, mutect2
- UBA6 | c.1684G>C p.D562H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV100451724, COSV59176999, COSV59181160; called by muse, mutect2, varscan2
- UBA6 | c.1500G>C p.L500F | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs779380702, COSV100451725; called by muse, mutect2, varscan2
- UBR1 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 24/119 reads (20%) | catalogued as COSV99317311; called by muse, mutect2, varscan2
- UBXN10 | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 35/125 reads (28%) | catalogued as COSV100907807; called by muse, mutect2, varscan2
- UFM1 | c.190+3_190+6del p.X64_splice | Splice Site (DEL) | VAF 28/116 reads (24%) | catalogued as rs867678548; called by mutect2, pindel, varscan2
- UNC5A | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99994638; called by muse, mutect2, varscan2
- UPF2 | c.2068-1G>A p.X690_splice | Splice Site (SNP) | VAF 27/116 reads (23%) | catalogued as COSV100707290; called by muse, mutect2, varscan2
- USP1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs1271136777, COSV100375225; called by muse, mutect2, varscan2
- USP3 | c.1544C>G p.A515G | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as COSV51427301, COSV99165723; called by muse, mutect2, varscan2
- USP34 | c.8481G>C p.K2827N | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV101277061; called by muse, mutect2, varscan2
- USP34 | c.5663G>A p.R1888H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs755411028, COSV68397918; called by muse, mutect2, varscan2
- USP38 | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.34); catalogued as COSV100189274; called by muse, mutect2, varscan2
- USP45 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV100569719; called by muse, mutect2, varscan2
- USP48 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as COSV100379421; called by muse, mutect2, varscan2
- UTP14A | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV100928967; called by muse, mutect2, varscan2
- VCAM1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.803); catalogued as COSV99658599; called by muse, mutect2, varscan2
- VPS13A | c.3735G>A p.M1245I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100652913; called by muse, mutect2, varscan2
- VPS53 | c.1474G>A p.E492K (on ENST00000571805 / NM_001366253.2; = p.E463K on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs778824142, COSV99346168; called by muse, mutect2, varscan2
- VPS53 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV99346169; called by muse, mutect2, varscan2
- VTCN1 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100061801, COSV60222753; called by muse, mutect2, varscan2
- WARS1 | c.609G>C p.W203C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100690189; called by muse, mutect2, varscan2
- WASHC5 | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100572854; called by muse, mutect2, varscan2
- WDR6 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780573025, COSV58245310; called by muse, mutect2, varscan2
- WIZ | c.5380G>A p.D1794N (on ENST00000673675 / NM_001371589.1; = p.D699N on NM_021241.3) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV54611170; called by muse, mutect2, varscan2
- XIRP2 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); catalogued as COSV54687771, COSV99743517; called by muse, mutect2, varscan2
- XYLB | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV99264227; called by muse, mutect2, varscan2
- ZFYVE26 | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); catalogued as COSV61328364; called by muse, mutect2, varscan2
- ZNF141 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as COSV99549743; called by muse, mutect2, varscan2
- ZNF16 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.542); catalogued as COSV99429680; called by muse, mutect2, varscan2
- ZNF208 | c.3041C>T p.S1014L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs759100623, COSV101237042, COSV101237101; called by muse, mutect2, varscan2
- ZNF235 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 46/162 reads (28%) | catalogued as COSV99349495; called by muse, mutect2, varscan2
- ZNF440 | c.1226C>G p.S409* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as COSV58372077; called by muse, mutect2, varscan2
- ZNF449 | c.1205C>G p.S402C | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); catalogued as COSV100202986; called by muse, mutect2, varscan2
- ZNF506 | c.1178G>C p.G393A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV101475638; called by muse, mutect2, varscan2
- ZNF532 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV100266664; called by muse, mutect2, varscan2
- ZNF532 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1182792459, COSV60173035; called by muse, mutect2, varscan2
- ZNF573 | c.482C>A p.P161H (on ENST00000536220 / NM_001172692.1; = p.P103H on NM_152360.3) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV100265654; called by muse, mutect2, varscan2
- ZNF582 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100018734, COSV100019043; called by muse, mutect2, varscan2
- ZNF654 | c.1776G>C p.K592N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100525783; called by muse, mutect2, varscan2
- ZNF675 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as COSV100705067; called by muse, mutect2, varscan2
- ZNF763 | c.439C>G p.Q147E (on ENST00000358987 / NM_001367172.2; = p.Q150E on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100676124; called by muse, varscan2
- ZNF763 | c.554C>T p.S185L (on ENST00000358987 / NM_001367172.2; = p.S188L on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100676058, COSV100676126; called by muse, varscan2
- ZNF770 | c.1549C>T p.H517Y | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100695982, COSV62544097; called by muse, mutect2, varscan2
- ZNF839 | c.406C>T p.R136W (on ENST00000558850 / NM_001267827.1; = p.R252W on NM_018335.5) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216272; called by muse, mutect2, varscan2
- ZSWIM5 | c.2401G>C p.E801Q | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100655582; called by muse, mutect2, varscan2
- ARHGEF18 | c.1905_1908del p.S635Rfs*8 (on ENST00000359920 / NM_001130955.2; = p.S531Rfs*8 on NM_015318.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel
- CCNB3 | c.1452dup p.T485Hfs*37 | Frame Shift Ins (INS) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- CGB8 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by mutect2, varscan2
- COL6A5 | c.6140del p.T2047Ifs*6 (on ENST00000312481; = p.T2043Ifs*6 on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- DOCK10 | c.4351del p.S1451Lfs*9 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- ETS2 | c.809_810del p.S270Wfs*10 | Frame Shift Del (DEL) | VAF 61/222 reads (27%) | called by mutect2, pindel, varscan2
- HNF1B | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.566); called by muse, mutect2
- KCNN2 | c.538_540del p.I180del (on ENST00000264773; = p.I392del on NM_021614.4) | In Frame Del (DEL) | VAF 30/100 reads (30%) | called by pindel, varscan2
- MTA2 | c.1011del p.T338Pfs*19 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- PITX1 | c.566dup p.A190Gfs*382 | Frame Shift Ins (INS) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- RBMXL1 | c.1066T>C p.Y356H | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.162); called by muse, varscan2
- SPANXB1 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 71/471 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ABCA1 | c.4410C>T p.I1470= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV101037066; called by muse, mutect2, varscan2
- ANKH | c.1182G>T p.L394= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99415123; called by muse, mutect2, varscan2
- ANLN | c.2454C>G p.V818= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV99732393; called by muse, mutect2, varscan2
- ARFIP2 | c.477G>A p.Q159= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1221745844, COSV99601547; called by muse, mutect2, varscan2
- ARSJ | c.1578C>T p.F526= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV59538638; called by muse, varscan2
- C1orf74 | c.10C>T p.L4= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV99161610; called by muse, mutect2, varscan2
- C5orf22 | c.735G>C p.G245= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100323506; called by muse, mutect2, varscan2
- CACNA1G | c.657C>T p.F219= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100661906; called by muse, mutect2, varscan2
- CADM2 | c.630C>T p.L210= (on ENST00000407528 / NM_001167674.2; = p.L212= on NM_153184.4) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101056327, COSV67382080, COSV67411355; called by muse, mutect2, varscan2
- CD28 | c.24C>T p.L8= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100142413; called by muse, mutect2, varscan2
- CDH23 | c.9540C>G p.V3180= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs776705226, COSV99821328; called by muse, mutect2, varscan2
- CFAP47 | c.1335G>C p.V445= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99935148; called by muse, mutect2, varscan2
- CHD2 | c.3756C>G p.V1252= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs141696596, COSV67713460; called by muse, mutect2, varscan2
- CHST8 | c.252G>A p.P84= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs373583449, COSV52863080; called by muse, mutect2, varscan2
- COL28A1 | c.2541G>A p.E847= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV101258650; called by muse, mutect2, varscan2
- COL4A6 | c.1413C>T p.G471= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV100564230; called by muse, mutect2, varscan2
- CPT1C | c.1992C>T p.L664= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV99773488; called by muse, mutect2, varscan2
- CRYBB3 | c.246G>A p.E82= | Silent (SNP) | VAF 52/214 reads (24%) | catalogued as COSV99309083; called by muse, mutect2, varscan2
- DACT1 | c.1113G>A p.L371= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100241894; called by muse, mutect2, varscan2
- DPP9 | c.111C>T p.I37= (on ENST00000598800; = p.I66= on NM_139159.5) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs773517372, COSV99506182; called by muse, mutect2, varscan2
- DPYSL5 | c.189C>T p.I63= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99981514, COSV99981534; called by muse, mutect2, varscan2
- ECHDC2 | c.168G>A p.L56= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs764022320, COSV100597635, COSV64301099; called by muse, mutect2, varscan2
- EEF2 | c.249G>A p.E83= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100500797; called by muse, mutect2, varscan2
- EFCC1 | c.1575G>A p.Q525= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101460000; called by muse, mutect2
- EML3 | c.1461G>A p.R487= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV53908531, COSV99609934; called by muse, mutect2, varscan2
- EPAS1 | c.496C>A p.R166= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV55390954, COSV99763273; called by muse, mutect2, varscan2
- FAM47A | c.1167G>A p.P389= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as rs201772377, COSV100649921; called by muse, varscan2
- FBXL8 | c.1077C>G p.L359= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV50461304; called by muse, mutect2, varscan2
- FGA | c.291G>A p.K97= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV100120422; called by muse, mutect2, varscan2
- FRMD3 | c.282C>T p.F94= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV100418787; called by muse, mutect2, varscan2
- FZD2 | c.969G>A p.K323= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100190486; called by muse, mutect2, varscan2
- FZD5 | c.375C>T p.F125= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1407775567, COSV54944839; called by muse, mutect2
- GABBR2 | c.2076C>T p.I692= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs141903124; ClinVar: likely benign; called by muse, mutect2, varscan2
- GNAT2 | c.216C>T p.I72= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as COSV63554733; called by muse, mutect2, varscan2
- GOLGB1 | c.9579C>T p.I3193= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV58860269; called by muse, mutect2, varscan2
- GPR32 | c.627C>A p.V209= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99567234; called by muse, mutect2
- GTF2F1 | c.240G>C p.R80= | Silent (SNP) | VAF 65/268 reads (24%) | catalogued as COSV101081264; called by muse, mutect2, varscan2
- HNRNPH2 | c.1311G>T p.L437= | Silent (SNP) | VAF 93/378 reads (25%) | catalogued as COSV57265553; called by muse, mutect2, varscan2
- HSPA2 | c.279C>T p.F93= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs781537634, COSV99904974; called by muse, mutect2, varscan2
- HSPH1 | c.348G>A p.Q116= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1193472552, COSV100184985; called by muse, mutect2, varscan2
- JCAD | c.831G>A p.K277= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs758612419, COSV100948396, COSV100948467; called by muse, mutect2, varscan2
- KIF13A | c.4434G>A p.K1478= | Silent (SNP) | VAF 115/346 reads (33%) | catalogued as COSV99436242; called by muse, mutect2, varscan2
- KLHL31 | c.489G>A p.L163= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100911795; called by muse, mutect2, varscan2
- KSR1 | c.2088C>T p.I696= (on ENST00000644974 / NM_001367810.1; = p.I581= on NM_014238.2) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99259715; called by muse, mutect2, varscan2
- LDHAL6A | c.900C>T p.I300= | Silent (SNP) | VAF 64/244 reads (26%) | catalogued as rs1453952104, COSV99324024; called by muse, mutect2, varscan2
- LRIG1 | c.990G>C p.L330= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1319851160, COSV99833835; called by muse, mutect2, varscan2
- LRRTM1 | c.1068C>T p.A356= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs771295054, COSV54446255; called by muse, mutect2, varscan2
- MAGEE1 | c.1779G>A p.L593= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100819412; called by muse, mutect2, varscan2
- MBD6 | c.912G>T p.L304= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV100851686; called by muse, mutect2, varscan2
- MDGA1 | c.2646C>T p.I882= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV99776984; called by muse, mutect2, varscan2
- MED29 | c.6G>A p.L2= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99655536; called by muse, mutect2, varscan2
- METTL2B | c.435G>A p.S145= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as rs764844976, COSV99299846; called by muse, mutect2, varscan2
- MEX3B | c.234C>T p.V78= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1328282546, COSV100314061; called by muse, varscan2
- MGAT4B | c.1617G>C p.L539= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99482234; called by muse, mutect2
- MTBP | c.1308G>A p.K436= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100012204; called by muse, mutect2, varscan2
- MTERF3 | c.669G>A p.L223= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99749815; called by muse, mutect2, varscan2
- MUC7 | c.564C>A p.T188= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as COSV100512320; called by muse, varscan2
- MYO9B | c.693G>A p.V231= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV101261597; called by muse, mutect2, varscan2
- NEB | c.15861C>G p.V5287= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as rs769437280, COSV99423932; called by muse, mutect2, varscan2
- NECTIN2 | c.1546C>T p.L516= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99375055; called by muse, mutect2, varscan2
- NOVA1 | c.999T>C p.G333= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs768040678, COSV99947790; called by muse, mutect2, varscan2
- NPIPB15 | c.810C>T p.L270= | Silent (SNP) | VAF 28/209 reads (13%) | catalogued as rs2868596, COSV70439054; called by muse, mutect2, varscan2
- OR2T1 | c.855C>T p.N285= | Silent (SNP) | VAF 64/206 reads (31%) | catalogued as COSV100822319; called by muse, mutect2, varscan2
- OR5AR1 | c.780G>C p.L260= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100265674; called by muse, mutect2, varscan2
- OR5M8 | c.543A>T p.P181= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV100510680; called by muse, mutect2, varscan2
- OTOA | c.2310C>T p.F770= (on ENST00000286149; = p.F756= on NM_144672.4) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99624584, COSV99624730; called by mutect2, varscan2
- PCDH15 | c.3699C>T p.S1233= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs774857947, COSV100217014; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCDHA2 | c.1329C>T p.I443= | Silent (SNP) | VAF 46/177 reads (26%) | catalogued as rs901353156, COSV65368307; called by muse, mutect2, varscan2
- PCDHGA12 | c.2430C>A p.A810= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV99340465; called by muse, mutect2, varscan2
- PGBD1 | c.1236C>G p.L412= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as rs941987594, COSV99460354; called by muse, mutect2, varscan2
- PLIN4 | c.3105C>G p.L1035= (on ENST00000301286; = p.L1050= on NM_001367868.2) | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100013386, COSV56689971; called by muse, mutect2, varscan2
- PRSS12 | c.948G>C p.V316= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99628323; called by muse, mutect2, varscan2
- PRSS54 | c.207C>T p.F69= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV54689940; called by muse, mutect2, varscan2
- PZP | c.4318C>T p.L1440= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV99738070; called by muse, mutect2, varscan2
- RBP3 | c.2340C>T p.I780= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs782527628; called by muse, mutect2, varscan2
- RSAD1 | c.1328G>A p.*443= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99364291; called by muse, mutect2, varscan2
- SCNN1B | c.1089G>A p.V363= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as COSV100225707; called by muse, mutect2, varscan2
- SLC39A7 | c.903G>C p.V301= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100807708; called by muse, mutect2, varscan2
- SLC45A3 | c.294G>A p.L98= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV65655323; called by muse, mutect2, varscan2
- SOX17 | c.1062C>A p.L354= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV52026322, COSV99810640; called by muse, mutect2, varscan2
- SPSB4 | c.447C>T p.L149= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100141449, COSV100141863; called by muse, mutect2
- SSH1 | c.1926G>A p.V642= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100425577; called by muse, mutect2, varscan2
- TENM1 | c.2805C>G p.V935= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100950197; called by muse, mutect2, varscan2
- TIMELESS | c.255G>A p.L85= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV99974027; called by muse, mutect2, varscan2
- TNFAIP3 | c.1947C>T p.S649= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs758623905, COSV99396824; called by muse, mutect2, varscan2
- TSPEAR | c.717G>T p.V239= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100553942; called by muse, mutect2, varscan2
- TTF1 | c.1920G>A p.K640= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100524729; called by muse, mutect2, varscan2
- UTRN | c.7077C>G p.L2359= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100839962; called by muse, mutect2, varscan2
- WDR19 | c.1941C>T p.D647= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs753924776, COSV99975562; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR72 | c.1623C>T p.L541= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as rs1425935458, COSV100854562; called by muse, mutect2, varscan2
- WSCD1 | c.1278G>A p.L426= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs759164480, COSV100496631; called by muse, varscan2
- ZBTB9 | c.114G>A p.L38= | Silent (SNP) | VAF 53/208 reads (25%) | catalogued as COSV101221763; called by muse, varscan2
- ZNF274 | c.414G>C p.L138= (on ENST00000610905; = p.L33= on NM_016324.3) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100464624, COSV100465149; called by muse, mutect2, varscan2
- ZNF532 | c.963C>T p.I321= | Silent (SNP) | VAF 45/204 reads (22%) | catalogued as rs149812809; called by muse, mutect2, varscan2
- ZNF630 | c.1908C>T p.F636= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV52095934; called by muse, mutect2, varscan2
- C2orf15 | c.-95C>G | 5'UTR (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100208996; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33764T>C | Intron (SNP) | VAF 24/112 reads (21%) | catalogued as COSV57777259; called by muse, mutect2, varscan2
- HCG27 | n.516C>T | RNA (SNP) | VAF 56/215 reads (26%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847787 G>C | 5'Flank (SNP) | VAF 44/192 reads (23%) | called by muse, mutect2, varscan2
- MAGEA4 | c.-97G>C | 5'UTR (SNP) | VAF 15/79 reads (19%) | catalogued as COSV99367519, COSV99367617; called by muse, mutect2, varscan2
- MICAL3 | c.2241+4619C>T | Intron (SNP) | VAF 33/155 reads (21%) | catalogued as COSV99261325; called by muse, mutect2, varscan2
- PDPN | c.-98C>A | 5'UTR (SNP) | VAF 17/49 reads (35%) | catalogued as rs868794296, COSV99611502; called by muse, mutect2, varscan2
